Gene-level copy-number profile of tumor specimen TCGA-FR-A3YO-06A from TCGA case TCGA-FR-A3YO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-FR-A3YO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.420f8ba6-a7c5-4421-8566-5d300182a5df.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FR-A3YO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3c918341-b540-4b42-93ad-770de3f34865

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 7,533; copy number 3: 20,012; copy number 4: 9,147; copy number 5: 14,801; copy number 6: 5,188; copy number 7: 2,475; copy number 8: 650.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FR-A3YO-06A-11D-A238-01): tumor purity 0.41, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,125 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:33,956,972–35,256,946, 8 genes, copy number 7 (within-gene range 6–7): LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P.
- chr3:35,650,197–35,651,961, 1 gene, copy number 7: ARPP21-AS1.
- chr7:57,819,819–159,233,377, 1,942 genes, copy number 7 (broad region; genes not listed).
- chr11:7,222,933–8,178,903, 34 genes, copy number 7: AC027804.1, MIR302E, SYT9, AC107884.1, OLFML1, PPFIBP2, AC107884.2, CYB5R2, OVCH2, AC104237.2, AC104237.3, AC044810.3, AC104237.1, OR10AB1P, OR5P4P, AC044810.2, OR5P1P, AC044810.1, OR5P2, OR5P3, OR5E1P, RNU6-943P, OR10A6, OR10A3, NLRP10, EIF3F, COX6CP5, CASC23, TUB, AC116456.1, TUB-AS1, AC116456.2, RIC3, RIC3-DT.
- chr11:68,612,899–114,518,371, 933 genes, copy number 7–8 (broad region; genes not listed).
- chr13:100,464,440–114,337,626, 207 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
